CPTAC case 01BR020 — Breast (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/e4ce89ef-bcaa-418a-8a6b-3602793b9bbf

Biospecimens (3 samples)
- Sample CPT008542: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples CPT008751, CPT008928 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
